Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0RU, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0RU-01A (Primary Tumor).

DEPARTMENT OF PATHOLOGY
SURGICAL PATHOLOGY REPORT

Carcinoma, infiltrating duct mixed w/ other types
(Metaplastic)
Site Codes: Breast, NOS C50.9 8523/3

Material
Submitted:
Clinical
History:
Clinical
Diagnosis:
Operating
Surgeon:

Left breast mass.

Pathology Number

Gross Examination:

A.) "Left breast mass". Tissue sent for ER/PR. In formalin. A single irregular piece of firm yellow and tan lobulated fibroadipose tissue which has been previously inked and partially cross sectioned measuring $3.0 \times 3.2 \times 2.4$ cm. On cut surface there is a poorly circumscribed firm gritty yellow-tan mass measuring approximately $2.7 \times 2.4 \times 1.8$ cm. in greatest dimensions. This mass grossly extends to within the surgical margins. Serially cross sectioned submitted in toto in **Blocks 1 through 7**.

MICROSCOPIC: The predominant component of the tumor is an infiltrating ductal carcinoma with almost no tubule formation. Extensive necrosis is seen in the infiltrating component. A minor component of comedo type intraductal carcinoma is seen at the periphery, making up less than a quarter of the tumor. Scattered through the tumor are multiple foci of sarcomatous metaplasia characterized by myxoid stroma of high cellularity with rudimentary cartilaginous differentiation. Although small foci of this metaplasia are scattered through the tumor, the epithelial component of the tumor predominates. Tumor extends to the margin of resection. The adjacent breast shows duct ectasia and papillary apocrine metaplasia.

DIAGNOSIS:

"LEFT BREAST MASS": COMEDO INTRADUCTAL AND INFILTRATING DUCTAL CARCINOMA NUCLEAR GRADE POORLY DIFFERENTIATED, HISTOLOGIC GRADE 3 OF 3 (2.7 CM. IN GREATEST DIAMETER), EXTENDING TO THE SURGICAL MARGIN. SARCOMATOUS METAPLASIA IS SEEN. SEE COMMENT.

COMMENT:

This case was reviewed by [redacted] and concurs.

Source: NCI Genomic Data Commons file fe9a11bb-689d-4c10-b9cc-6ed8d222b1e7 (TCGA-B6-A0RU.39C689CA-F7BA-4554-BEC8-11F9C8142D9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).